Somatic mutation profile of tumor specimen ALCH-B48D-TTP1-A (aliquot ALCH-B48D-TTP1-A-1-0-D-A799-36) from ALCHEMIST case ALCH-B48D, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 52.5 years (19,187 days).
Specimen ALCH-B48D-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9c835635-8e65-423a-8614-60f15c190a4a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B48D-NB1-A (Blood Derived Normal), aliquot ALCH-B48D-NB1-A-1-0-D-A799-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ec55428-5946-46cb-b174-b72a512ddd5e

The open-access MAF lists 35 somatic variants for this specimen: 27 protein-altering or splice-affecting, 3 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 3, Intron 1, 3'Flank 1, 5'UTR 1, Frame Shift Del 1, In Frame Del 1, RNA 1, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 50/488 reads (10%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel
- TP53 | c.638G>T p.R213L | Missense Mutation (SNP) | VAF 35/335 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs587778720, CM004906, CM022474, COSV52665093, COSV52668963, COSV52693072; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CCDC60 | c.583A>G p.I195V | Missense Mutation (SNP) | VAF 24/219 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0.015); catalogued as rs775117225; called by muse, mutect2, varscan2
- DDX17 | c.2110A>T p.T704S | Missense Mutation (SNP) | VAF 38/444 reads (9%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.007); catalogued as COSV99317966; called by muse, mutect2
- GRM4 | c.2456C>A p.T819K | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV65211054; called by muse, mutect2
- PGK2 | c.1068G>T p.M356I | Missense Mutation (SNP) | VAF 36/402 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.858); catalogued as COSV59165480; called by muse, mutect2
- RUNX1 | c.1007G>C p.G336A (on ENST00000344691 / NM_001001890.3; = p.G363A on NM_001754.5) | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.075); catalogued as rs777498866; called by muse, mutect2
- SETMAR | c.641A>T p.Y214F | Missense Mutation (SNP) | VAF 24/176 reads (14%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.232); catalogued as rs913065211; called by muse, mutect2, varscan2
- TENM3 | c.2878G>A p.V960M | Missense Mutation (SNP) | VAF 20/284 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.166); catalogued as rs777457308, COSV101304973; called by muse, mutect2
- TNKS1BP1 | c.2260C>G p.Q754E | Missense Mutation (SNP) | VAF 17/377 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.124); catalogued as COSV100836194; called by muse, mutect2
- UBR4 | c.2569C>T p.R857C | Missense Mutation (SNP) | VAF 23/291 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV64386625; called by muse, mutect2
- ZNF665 | c.1423A>T p.K475* (on ENST00000600412; = p.K540* on NM_024733.5 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 11/97 reads (11%) | catalogued as COSV67213511; called by muse, mutect2
- DICER1 | c.5338A>T p.N1780Y | Missense Mutation (SNP) | VAF 14/458 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2
- EIF2B5 | c.1430C>G p.S477C (on ENST00000647909; = p.S469C on NM_003907.3) | Missense Mutation (SNP) | VAF 47/470 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- FHL5 | c.326T>A p.I109N | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, varscan2
- FREM1 | c.203T>A p.I68K | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- GPR22 | c.602A>G p.N201S | Missense Mutation (SNP) | VAF 6/143 reads (4%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.983); called by muse, mutect2
- KRT8 | c.145G>A p.G49S | Missense Mutation (SNP) | VAF 12/327 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.251); called by muse, mutect2
- LAMC2 | c.2100G>A p.M700I | Missense Mutation (SNP) | VAF 52/554 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.031); called by muse, mutect2
- LARP4 | c.716A>T p.Y239F | Missense Mutation (SNP) | VAF 10/131 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2
- LCP2 | c.234G>T p.R78S | Missense Mutation (SNP) | VAF 10/303 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.135); called by muse, mutect2
- NES | c.2126A>G p.E709G | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- PIGZ | c.175C>G p.P59A | Missense Mutation (SNP) | VAF 49/390 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POLQ | c.7432G>C p.A2478P | Missense Mutation (SNP) | VAF 14/215 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SOX7 | c.670T>A p.C224S | Missense Mutation (SNP) | VAF 12/262 reads (5%) | SIFT tolerated (0.55); PolyPhen benign (0.18); called by muse, mutect2
- TMPRSS7 | c.1924_1942del p.L642Ffs*30 (on ENST00000452346; = p.L516Ffs*30 on NM_001042575.2) | Frame Shift Del (DEL) | VAF 4/50 reads (8%) | called by mutect2, pindel
- TOGARAM1 | c.4591A>T p.I1531F | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); called by muse, varscan2
- C2orf78 | c.2607G>A p.T869= | Silent (SNP) | VAF 33/318 reads (10%) | catalogued as rs750694636; called by muse, mutect2, varscan2
- OR7C1 | c.477G>A p.E159= | Silent (SNP) | VAF 20/228 reads (9%) | called by muse, mutect2
- TSPEAR | c.339G>A p.E113= | Silent (SNP) | VAF 8/216 reads (4%) | catalogued as rs1234305837; called by muse, mutect2
- GPR89B | chr1:147995666 T>G | 3'Flank (SNP) | VAF 60/550 reads (11%) | called by muse, mutect2, varscan2
- GUCY2EP | n.1395G>T | RNA (SNP) | VAF 12/195 reads (6%) | called by muse, mutect2
- ITLN2 | c.-28G>A | 5'UTR (SNP) | VAF 28/240 reads (12%) | catalogued as COSV100600729; called by muse, mutect2, varscan2
- KLK12 | c.*2C>A | 3'UTR (SNP) | VAF 60/464 reads (13%) | called by muse, mutect2, varscan2
- PGM1 | c.247-5849G>T | Intron (SNP) | VAF 22/327 reads (7%) | called by muse, mutect2
